Somatic mutation profile of tumor specimen 0DQWS3 from CCDI case PBCFUI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Chordoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,367 days).
Specimen 0DQWS3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5843eaff-11c9-4e5b-93c4-a20af5034f9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQWS5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c24086a-606f-4302-b579-88ebbd763898

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 5, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011479.1 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 270/994 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs532051981; called by muse, mutect2, varscan2
- NRCAM | c.540G>C p.W180C (on ENST00000379028 / NM_001371124.1; = p.W174C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/817 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61036704; called by muse, varscan2
- XKR4 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 185/1259 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.572); catalogued as rs761395206, COSV59297915; called by muse, mutect2, varscan2
- DHRS9 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 134/816 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, varscan2
- FIZ1 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 78/526 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MPHOSPH9 | c.1637A>G p.D546G | Missense Mutation (SNP) | VAF 38/1124 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SORD | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 128/846 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XIRP2 | c.2357A>T p.D786V (on ENST00000628543; = p.D961V on NM_152381.6) | Missense Mutation (SNP) | VAF 129/950 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by mutect2, varscan2
- AGTPBP1 | c.2736C>T p.Y912= (on ENST00000357081 / NM_001330701.2; = p.Y872= on NM_015239.2) | Silent (SNP) | VAF 83/615 reads (13%) | catalogued as rs758303138; called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 30/540 reads (6%) | catalogued as rs1167537044; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 53/1053 reads (5%) | called by muse, mutect2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 14/122 reads (11%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 14/122 reads (11%) | called by muse, varscan2
- KCNMA1 | c.3016+951G>C | Intron (SNP) | VAF 22/622 reads (4%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- SDK1 | c.1994+15G>A | Intron (SNP) | VAF 98/765 reads (13%) | catalogued as rs753532013; called by muse, mutect2, varscan2
